Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A2OX, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A2OX-01A (Primary Tumor).

[page 1 of 3]
LABORATORY MEDICINE PROGRAM

Surgical Pathology Consultation Report

Patient
Name:
MRN:
DOB:
Gender: M
HCN:
Ordering
MD:
Copy To:

Service:
Visit #:
Location:
Facility:

Accession #:
Collected:
Received:
Reported:

Specimen(s) Received

1. Thyroid: total- stitch marks right superior pole
2. Lymph node: Rt. and central paratracheal nodes

Diagnosis

1. Multifocal papillary carcinoma, dominant widely invasive classical variant with psammomatous dissemination, 1.8 cm, right; and mild follicular nodular disease: Thyroid, total thyroidectomy specimen. See Comment.
2. Metastatic papillary thyroid carcinoma: Lymph nodes, 8 of 9 (right neck and central paratracheal) dissection specimen

Comment

The dominant 1.8 cm tumor shows an aggressive histological pattern with diffuse invasive growth and intrathyroidal psammomatous dissemination. There is also focal tall cell change (less than 5%). There is definitive lymphatic invasion and few foci suspicious for, but not definitive for vascular invasion. Both the dominant 1.8 cm and the second dominant 0.6 cm lesions come within 0.1 mm of the painted resection margin.

Synoptic Data

Procedure:

Other: Total thyroidectomy with right neck and central paratracheal dissection.

Received:

Fresh

Specimen Integrity:

Intact

Specimen Size:

Right lobe:

4.5 cm

3.4 cm

1.6 cm

Left lobe:

4.5 cm

2.0 cm

ICB-0-3
carcinoma, papillary, thyroid
8260/3

Site: Thyroid, NOS C 73.9

8/24/11

[page 2 of 3]
	1.0 cm
	Isthmus +/- pyramidal lobe:
	2.1 cm
	2.5 cm
	1.2 cm
	Additional specimen: right and central paratracheal node
	dissection.
	4.5 cm
	2.3 cm
	1.9 cm
Specimen Weight:	25.6 g
Tumor Focality:	Multifocal, ipsilateral
	Multifocal, midline (isthmus)
----- DOMINANT TUMOR -----	
Tumor Laterality:	Right lobe
Tumor Size:	Greatest dimension: 1.8cm
	Additional dimension: 1.5 cm
	Additional dimension: 1.4 cm
Histologic Type:	Papillary carcinoma, classical (usual)
	Papillary carcinoma, other variant: focal tall cell change (<5%)
	Classical (papillary) architecture
	Classical cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
	Distance of invasive carcinoma to closest margin: 0.1mm
Tumor Capsule:	Partially encapsulated
Tumor Capsular Invasion:	Present, extent widely invasive
Lymph-Vascular Invasion:	Indeterminate
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
----- SECOND TUMOR -----	
Tumor Laterality:	Isthmus
Tumor Size:	Greatest dimension: 0.6cm
Histologic Type:	Papillary carcinoma, classical (usual)
	Classical (papillary) architecture
	Classical cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
	Distance of invasive carcinoma to closest margin: 0.1mm
Tumor Capsule:	Partially encapsulated
Tumor Capsular Invasion:	Present, extent minimal
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
TNM Descriptors:	m (multiple primary tumors)
Primary Tumor (pT):	pT1b: Tumor more than 1 cm but not more than 2 cm in
	greatest dimension, limited to the thyroid
Regional Lymph Nodes (pN):	pN1b: Metastases to unilateral, bilateral or contralateral
	cervical or superior mediastinal lymph nodes
	Number of regional lymph nodes examined: 9
	Number of regional lymph nodes involved: 8
	Lymph Node, Extranodal Extension Not identified
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Adenomatoid nodule(s) or Nodular follicular disease
	Thyroiditis, palpation

[page 3 of 3]
verified by:

Electronically

Gross Description

1. The specimen labeled with the patient's name and as "total thyroid stitch marks right superior pole" consists of a thyroid gland that is oriented with a stitch marking the superior pole and weighs 25.6 g. The right lobe measures 4.5 cm SI x 3.4 cm ML x 1.6 cm AP, the left lobe measures 4.5 cm SI x 2.0 cm ML x 1.0 cm AP and the isthmus measures 2.1 cm SI x 2.5 cm ML x 1.2 cm AP. The external surfaces have fibrous adhesions and are painted with silver nitrate. No parathyroid glands or no lymph nodes are identified grossly. The mid right lobe contains one well delineated nodule that measures 1.4 cm SI x 1.8 cm ML x 1.5 cm AP. A second nodule is identified on the isthmus measuring 0.6 SI x 0.6 ML x 0.5 cm AP. The cut surface of both nodules is homogeneous tan in color, solid and firm. The remainder of the thyroid tissue is homogeneous brown in color and grossly unremarkable. Sections of right lobe nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

1A-I right lobe, superior to inferior

1J-M isthmus

1N-T left lobe, superior to inferior

2. The specimen is labeled with the patient's name and "right neck and central paratracheal lymph node" consists of portion of fibroadipose tissue that measures 4.5 x 2.3 x 1.9 cm. Multiple lymph nodes ranging from 0.3 x 0.3 x 0.2 cm to 0.9 x 0.8 x 0.6 cm are identified. Representative sections are submitted.

2A multiple lymph nodes

2B multiple lymph nodes

2C one lymph node bisected

Source: NCI Genomic Data Commons file 80545e48-9679-40bb-aca6-36d30dbd7b18 (TCGA-EM-A2OX.8BC70A7D-F4F4-4268-88DC-4F7A6B30D67A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).